Somatic mutation profile of tumor specimen TCGA-LN-A49S-01A (aliquot TCGA-LN-A49S-01A-11D-A247-09) from TCGA case TCGA-LN-A49S, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 59.9 years (21,865 days).
Specimen TCGA-LN-A49S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6629296e-381d-427a-aa53-f540dab048cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49S-10A (Blood Derived Normal), aliquot TCGA-LN-A49S-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62588e44-6dbf-48cd-b972-ec9bfc85d85b

The open-access MAF lists 145 somatic variants for this specimen: 99 protein-altering or splice-affecting, 41 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 41, Nonsense Mutation 5, RNA 4, Frame Shift Del 2, Nonstop Mutation 1, Intron 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.077); catalogued as rs387906592, CM106014, CM126715; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACSM2A | c.1431G>T p.E477D (on ENST00000219054; = p.E398D on NM_001308169.2) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs759108235; called by muse, mutect2
- ARX | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV66875859; called by muse, mutect2
- BCAR1 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1301916801; called by muse, mutect2, varscan2
- C1GALT1 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs773916621; called by mutect2, varscan2
- CCT5 | c.238A>G p.M80V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs779876496; called by muse, mutect2, varscan2
- CEP152 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs146482586, COSV57864990; called by muse, mutect2, varscan2
- CLCN2 | c.559G>C p.A187P | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs956240636; called by muse, mutect2, varscan2
- COL28A1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs756091636, COSV68080356, COSV68082746; called by muse, mutect2
- CSMD3 | c.7384C>T p.R2462W (on ENST00000297405 / NM_001363185.1; = p.R2358W on NM_052900.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs199998952, COSV52239525; called by muse, mutect2, varscan2
- CTNND1 | c.2830C>G p.L944V (on ENST00000399050 / NM_001085458.2; = p.L917V on NM_001331.3) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.099); catalogued as COSV62383167, COSV62385348; called by muse, mutect2
- DEPDC7 | c.245A>G p.N82S (on ENST00000241051 / NM_001077242.2; = p.N73S on NM_139160.2) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.887); catalogued as rs778104021; called by muse, mutect2, varscan2
- DNAJA3 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs747052248, COSV99276864; called by muse, mutect2
- EDC4 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151306360, COSV100197361; called by muse, mutect2, varscan2
- F7 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs546856641; called by muse, mutect2, varscan2
- GLUL | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs1248190693; called by muse, mutect2, varscan2
- GP2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374063505, COSV56896525; called by muse, mutect2, varscan2
- HOGA1 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs764224799, COSV56731360; called by muse, mutect2, varscan2
- HOXD13 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66832641; called by muse, mutect2
- IFIT1 | c.730C>G p.L244V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs772301237; called by muse, mutect2, varscan2
- KCTD14 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374366969; called by muse, mutect2, varscan2
- LDHAL6A | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99324000; called by muse, mutect2
- LEO1 | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs977756233; called by muse, mutect2, varscan2
- LONP1 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs768949488, COSV61501777; called by mutect2, varscan2
- LRRN3 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV57817369; called by muse, mutect2
- MAN1C1 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99056272; called by muse, mutect2, varscan2
- MMP11 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs767691945; called by muse, mutect2, varscan2
- MOK | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs746962840, COSV51963284; called by muse, mutect2, varscan2
- MRPL58 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs779805621, COSV99041779; called by muse, mutect2, varscan2
- MTUS2 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV101462333, COSV70916454; called by muse, mutect2
- PCDHB10 | c.2185G>C p.V729L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.125); catalogued as COSV53375332; called by muse, mutect2, varscan2
- PSPN | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751627297; called by muse, mutect2, varscan2
- RAP2C | c.297A>T p.Q99H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV61683482; called by muse, mutect2, varscan2
- RTN4RL1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.364); catalogued as COSV100486394; called by muse, mutect2, varscan2
- SAPCD1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1268934031; called by muse, mutect2
- SEC24C | c.1528G>T p.V510F | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59541144; called by muse, mutect2
- SH3GL2 | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.43); catalogued as COSV66047349; called by muse, mutect2
- TMC4 | c.940C>T p.R314C (on ENST00000617472 / NM_001145303.3; = p.R308C on NM_144686.4) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1450371845; called by muse, mutect2
- TRPM6 | c.4033C>T p.L1345F | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV62516565; called by muse, mutect2
- TTN | c.46744C>T p.R15582* (on ENST00000591111; = p.R8158* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as rs748956593; called by muse, mutect2, varscan2
- VAV1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs749873161, COSV58383552, COSV58390451; called by muse, mutect2, varscan2
- ZBTB16 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1441168617; called by muse, mutect2
- AGL | c.3323G>C p.R1108T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- ALKBH5 | c.926A>T p.D309V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- ARHGEF9 | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- BCL9 | c.1819C>G p.P607A | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- CA7 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- CACNA1S | c.2156A>G p.K719R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CAPN13 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CDC6 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.143); called by muse, mutect2
- CDH10 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CEP135 | c.1148G>C p.S383T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP290 | c.5122C>T p.L1708F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CHRNA5 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- COL2A1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CSMD2 | c.3791T>C p.L1264P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1547A>G p.N516S | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- E2F7 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESYT1 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.027); called by muse, mutect2
- FAT3 | c.6011T>C p.V2004A | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FRMD4A | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- HECTD2 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- INO80B | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- ITK | c.1298T>G p.L433R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCTD8 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.831); called by muse, mutect2
- KIFAP3 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- KMT2D | c.2798del p.D933Vfs*25 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- KMT5C | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- LRP1B | c.9736G>A p.A3246T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MGAT4A | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOCS3 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO9B | c.5111G>A p.S1704N | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2
- NDUFAF7 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- NEK7 | c.150A>T p.R50S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- OR6B1 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCSK5 | c.5347G>T p.A1783S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PI4KA | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- POGZ | c.1451T>C p.L484P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRRC1 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRM | c.3522G>A p.M1174I | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.838); called by muse, mutect2
- RBBP5 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RCC2 | c.799A>G p.M267V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.949); called by muse, mutect2
- RNPC3 | c.1411A>C p.I471L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- RRAGB | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RRP15 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SAMHD1 | c.1298C>G p.S433C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC7A7 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- SRSF10 | c.789A>G p.*263Wext*1 | Nonstop Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- STRIP1 | c.1533A>T p.Q511H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TCTEX1D2 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TJP1 | c.2882del p.P961Qfs*14 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- UGT1A6 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP5 | c.1495A>G p.K499E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- WASHC2C | c.2222C>G p.S741C | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- ZNF324 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF609 | c.1828G>C p.D610H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.189); called by muse, mutect2
- ZNF750 | c.11_12insTT p.K5Sfs*41 | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- ABI1 | c.384G>A p.A128= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs558636392; called by muse, mutect2, varscan2
- ACAD11 | c.2331A>G p.T777= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- AKNA | c.858A>G p.R286= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- AL645922.1 | c.1977C>A p.I659= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1051693374, COSV54960556; called by muse, mutect2
- BCOR | c.4374C>G p.V1458= (on ENST00000378444 / NM_001123385.2; = p.V1424= on NM_017745.6) | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CA8 | c.372G>A p.Q124= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- CCDC102A | c.1554C>T p.L518= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- CENPO | c.396G>T p.G132= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- CPED1 | c.2490G>A p.L830= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- DCC | c.3939G>C p.L1313= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- FAIM2 | c.540C>A p.A180= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- FHOD1 | c.2163C>G p.L721= | Silent (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- GREM1 | c.51C>G p.T17= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- IGHD3-22 | c.11G>A p.*4= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as rs547532541; called by muse, mutect2
- ITPR3 | c.5358C>T p.F1786= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs747022423; called by muse, mutect2, varscan2
- IVD | c.574C>T p.L192= (on ENST00000651168; = p.L189= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- LRRC43 | c.1194C>T p.V398= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV60289430; called by muse, mutect2
- MSTO1 | c.1188A>G p.P396= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- NDST2 | c.1836G>A p.Q612= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- NKIRAS1 | c.264G>A p.V88= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- NLRC3 | c.2034C>T p.I678= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- NPY1R | c.63G>A p.K21= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs761308479, COSV56713374; called by mutect2, varscan2
- NRXN3 | c.3070T>C p.L1024= (on ENST00000335750 / NM_001330195.2; = p.L651= on NM_004796.6) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV59757414; called by muse, mutect2, varscan2
- PLEKHG3 | c.3486C>T p.V1162= (on ENST00000394691; = p.V1218= on NM_001308147.2) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs752022533; called by muse, mutect2, varscan2
- PLXNA2 | c.159G>A p.L53= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- PUM1 | c.825G>C p.V275= | Silent (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- RNF43 | c.720C>T p.I240= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV68457311; called by muse, mutect2, varscan2
- RP2 | c.51C>A p.P17= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- SEMA4C | c.864G>A p.P288= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs141614070; called by muse, mutect2, varscan2
- SERPING1 | c.945C>T p.F315= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as CD143216, COSV53542189; called by muse, mutect2, varscan2
- SLC39A4 | c.630C>T p.F210= (on ENST00000301305 / NM_001374839.1; = p.F185= on NM_017767.3) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs782268389; called by muse, mutect2, varscan2
- SLITRK2 | c.387C>A p.T129= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- TAF3 | c.756T>A p.V252= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- TECRL | c.513A>G p.G171= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV101168993; called by muse, mutect2, varscan2
- TXNDC2 | c.561C>T p.I187= (on ENST00000306084 / NM_001098529.2; = p.I120= on NM_032243.6) | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- VPS16 | c.2286C>T p.I762= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100988520; called by muse, mutect2, varscan2
- VPS39 | c.891G>T p.V297= (on ENST00000348544 / NM_001301138.2; = p.V286= on NM_015289.5) | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- VWA5A | c.1959G>A p.K653= | Silent (SNP) | VAF 4/87 reads (5%) | called by muse, mutect2
- XYLT1 | c.2847G>A p.L949= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- ZFP42 | c.51G>T p.L17= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.945C>T p.R315= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs370513764; called by muse, mutect2, varscan2
- ATXN7L1 | c.355+27175C>A | Intron (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.29C>T | RNA (SNP) | VAF 10/35 reads (29%) | catalogued as rs1188357072; called by muse, mutect2, varscan2
- DCHS2 | n.3951G>C | RNA (SNP) | VAF 7/38 reads (18%) | catalogued as rs759769096, COSV100601557, COSV61767998, COSV61774246; called by muse, mutect2
- DCHS2 | n.376G>A | RNA (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- MIR498 | n.27G>A | RNA (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
